FM case AD6891 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/828cf2e6-2f8a-4fec-84c9-c48f3f606f51

Male, 44.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the appendix; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
